Gene-level copy-number profile of tumor specimen HTMCP-02-01-01022-01A from CGCI case HTMCP-02-01-01022, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS.
Specimen HTMCP-02-01-01022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 72139b8a-349e-4015-a818-5479b78acee7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-01-01022-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/3d7f00cf-403c-4c1b-8200-881bd676c276

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,147; copy number 2: 40,818; copy number 3: 9,651; copy number 4: 2,568; copy number 5: 427; copy number 6: 226; copy number 7: 27; copy number 8: 2; copy number 9: 3; copy number 11: 12; copy number 13: 17; copy number 23: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 715 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–827,796, 51 genes, copy number 6 (within-gene range 4–6): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3, AL669831.1, RNU6-1199P, AL669831.2, LINC01409, AL669831.6, AL669831.4, FAM87B.
- chr1:118,614,333–120,842,110, 53 genes, copy number 5–11: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr1:120,913,184–121,580,524, 23 genes, copy number 7–13 (within-gene range 3–13): LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:143,784,376–145,242,124, 45 genes, copy number 6: AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr1:222,477,252–222,519,732, 3 genes, copy number 9: AL513314.2, RNU6-791P, AL592148.2.
- chr1:242,975,005–243,101,744, 7 genes, copy number 6: AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr1:248,436,359–248,574,757, 11 genes, copy number 5: OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34.
- chr2:111,006,015–111,523,376, 1 gene, copy number 5 (within-gene range 2–5): MIR4435-2HG.
- chr2:111,265,283–111,384,992, 5 genes, copy number 5: AC068491.1, AC068491.2, RPS14P4, MIR4435-2, PAFAH1B1P2.
- chr2:111,742,586–111,744,662, 1 gene, copy number 5: CENPNP2.
- chr2:113,325,372–113,425,548, 1 gene, copy number 5 (within-gene range 2–5): AC016745.1.
- chr2:113,432,600–113,658,675, 15 genes, copy number 5: AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1.
- chr3:161,816,909–180,989,774, 242 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:49,246,021–49,589,529, 14 genes, copy number 6: MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:175,903,874–176,126,959, 9 genes, copy number 5 (within-gene range 3–5): AC138965.2, AC138965.1, THOC3, THOC3-AS1, OR1X1P, AC139491.3, AC139491.1, FAM153B, AC139491.7.
- chr5:177,682,294–177,950,732, 7 genes, copy number 5 (within-gene range 0–5): AC138819.1, FAM153A, AC140125.2, AC140125.1, AC106795.1, OR1X5P, AC140125.3.
- chr5:181,246,507–181,342,213, 9 genes, copy number 5 (within-gene range 3–5): CTC-338M12.4, TRIM52, TRIM52-AS1, AC008443.2, AC008443.5, RNU6-705P, AC138035.1, AC138035.3, AC138035.2.
- chr7:102,471,469–102,809,225, 18 genes, copy number 5: MIR4467, POLR2J, RASA4B, POLR2J3, UPK3BL2, AC093668.1, SPDYE2, POLR2J3, RASA4, AC105052.4, AC105052.1, UPK3BL1, AC105052.3, SPDYE2B, POLR2J2, RASA4DP, FAM185A, AC105052.2.
- chr9:38,804,007–38,851,916, 1 gene, copy number 6: AL845311.1.
- chr9:62,710,036–63,385,117, 20 genes, copy number 5–6: FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1.
- chr9:64,369,394–64,889,063, 18 genes, copy number 5: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr9:66,721,158–68,330,626, 33 genes, copy number 5 (within-gene range 3–5): ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4, AL353770.2, FAM74A3, AL353770.3, AL353770.1, SPATA31A3, CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1, BX664730.1, Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1.
- chr12:12,310–38,133, 3 genes, copy number 5: DDX11L8, WASH8P, FAM138D.
- chr14:18,333,726–18,412,264, 3 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2.
- chr15:32,175,247–32,615,158, 24 genes, copy number 5 (within-gene range 2–5): Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3, AC123768.2, GOLGA8N, RN7SL286P.
- chr16:14,695,567–14,707,055, 1 gene, copy number 5: AC009167.1.
- chr16:15,104,312–15,362,674, 8 genes, copy number 5 (within-gene range 3–5): NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1, AC137803.1.
- chr16:29,483,642–29,505,999, 1 gene, copy number 6: NPIPB12.
- chr16:33,827,214–33,827,661, 1 gene, copy number 23: IGHV3OR16-13.
- chr16:33,907,419–33,950,420, 4 genes, copy number 6–7: ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:46,243,606–46,757,464, 14 genes, copy number 6: MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B, NSF, RPS7P11.
- chr20:32,561,093–32,608,893, 3 genes, copy number 5 (within-gene range 3–5): AL133343.2, NOL4L-DT, AL133343.1.
- chr21:7,744,962–8,987,430, 36 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1.
- chr21:9,053,122–9,368,775, 6 genes, copy number 5–6: CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12.
- chr22:15,282,557–15,644,330, 18 genes, copy number 5: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7.
- chr22:15,699,361–15,703,403, 2 genes, copy number 5 (within-gene range 3–5): POTEH-AS1, RNU6-816P.

Autosomal genes at a single copy (total copy number 1): 3,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
